Somatic mutation profile of tumor specimen 4d86cf19-8d5b-46b5-ab4c-ace0b2 (aliquot 4d86cf19-8d5b-46b5-ab4c-ace0b2_D6) from CPTAC case 22CO006, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC.
Specimen 4d86cf19-8d5b-46b5-ab4c-ace0b2: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abef8e19-ba73-4113-a54d-bbfd84bdbbc6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 3487b5c2-1dce-4e1c-bb84-30e8f2 (Blood Derived Normal), aliquot 3487b5c2-1dce-4e1c-bb84-30e8f2_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0cf8aa73-0257-4635-9d41-8490a2f4f79c

The open-access MAF lists 1,282 somatic variants for this specimen: 869 protein-altering or splice-affecting, 261 silent, 152 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 614, Silent 261, Frame Shift Del 156, Intron 74, Nonsense Mutation 35, Frame Shift Ins 27, 3'UTR 27, Splice Region 17, 5'UTR 17, RNA 15, Splice Site 13, 3'Flank 10.

Variants (750 of 1,282; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARX | c.1187del p.P396Lfs*67 | Frame Shift Del (DEL) | VAF 14/112 reads (13%) | catalogued as rs1328291159; ClinVar: pathogenic; called by mutect2, varscan2
- BBS10 | c.235dup p.T79Nfs*17 | Frame Shift Ins (INS) | VAF 18/138 reads (13%) | catalogued as rs760693838; ClinVar: pathogenic; called by mutect2, varscan2
- BMPR2 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 25/193 reads (13%) | catalogued as rs137852753, CM010161, COSV65807978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CACNA1A | c.4045C>T p.R1349* | Nonsense Mutation (SNP) | VAF 26/235 reads (11%) | catalogued as rs1568473233, CM129333, COSV100802972; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMD | c.5533G>T p.E1845* | Nonsense Mutation (SNP) | VAF 24/201 reads (12%) | catalogued as rs1354256883, CM116912; ClinVar: pathogenic; called by mutect2, varscan2
- DYNC2H1 | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as rs770380730, COSV62086638; ClinVar: pathogenic; called by mutect2, varscan2
- GCDH | c.1198G>A p.V400M | Missense Mutation (SNP) | VAF 54/524 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs121434372, CM960718, COSV99535611; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LRPPRC | c.3147del p.A1051Hfs*6 | Frame Shift Del (DEL) | VAF 18/148 reads (12%) | catalogued as rs769022521; ClinVar: pathogenic; called by mutect2, varscan2
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 12/109 reads (11%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, pindel
- MSX2 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 40/347 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs104893896, CM001249, COSV53326898; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RHOA | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 8/70 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs1057519953, COSV69041526, COSV69042045; ClinVar: likely pathogenic; called by mutect2, varscan2
- SCN2A | c.386+2T>C p.X129_splice | Splice Site (SNP) | VAF 14/136 reads (10%) | catalogued as rs1553564400; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC5 | c.1042G>A p.V348M | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.389); catalogued as rs761217800, COSV55593980; called by mutect2, varscan2
- ABITRAM | c.539C>T p.T180M | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.23); catalogued as rs138152954; called by mutect2, varscan2
- ABLIM2 | c.1042G>T p.G348C | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); catalogued as rs779669855; called by muse, mutect2, varscan2
- ACACB | c.4849C>T p.R1617C | Missense Mutation (SNP) | VAF 44/281 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs753880349; called by muse, mutect2, varscan2
- ACLY | c.2053G>A p.V685M | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs1555628085, COSV100709930; called by muse, mutect2, varscan2
- ACLY | c.867C>T p.S289= | Splice Region (SNP) | VAF 20/179 reads (11%) | catalogued as rs1281001958, COSV61251349; called by muse, mutect2
- ACP4 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.903); catalogued as rs765260771; called by muse, mutect2, varscan2
- ACSM2B | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs375844763; called by muse, mutect2, varscan2
- ACTB | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 42/526 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.077); catalogued as COSV59320376; called by muse, mutect2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 13/76 reads (17%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS19 | c.1235A>G p.E412G | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.772); catalogued as rs1429187560; called by muse, mutect2
- ADAMTS5 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 28/382 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as COSV53175743, COSV53185907; called by muse, mutect2
- ADARB2 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs1225574207, COSV101187133; called by muse, mutect2, varscan2
- ADCK1 | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs552612645; called by muse, mutect2
- ADCY1 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as rs536487311, COSV52032873; called by muse, mutect2, varscan2
- ADCY7 | c.837-1G>A p.X279_splice | Splice Site (SNP) | VAF 13/103 reads (13%) | catalogued as COSV54266671; called by muse, mutect2, varscan2
- ADGRB1 | c.3118G>A p.V1040M | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs901603541, COSV60102380; called by muse, mutect2
- ADGRB2 | c.3536G>A p.R1179H | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs202211069, COSV99927157; called by muse, mutect2, varscan2
- ADGRF4 | c.506del p.N169Ifs*15 | Frame Shift Del (DEL) | VAF 11/123 reads (9%) | catalogued as rs1178459999; called by mutect2, pindel
- ADI1 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as rs766432559; called by muse, mutect2, varscan2
- ADPRS | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768003962, COSV52880793; called by muse, mutect2, varscan2
- AFF1 | c.632T>G p.L211W | Missense Mutation (SNP) | VAF 35/303 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751228827; called by muse, mutect2, varscan2
- AGRN | c.2665G>A p.A889T | Missense Mutation (SNP) | VAF 52/378 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.144); catalogued as rs751073264; called by muse, mutect2, varscan2
- AIP | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 62/511 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.024); catalogued as rs139947406; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH1A3 | c.849del p.K284Rfs*83 | Frame Shift Del (DEL) | VAF 26/198 reads (13%) | catalogued as rs758955164; called by mutect2, varscan2
- ALDH1L1 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs370724859; called by muse, mutect2, varscan2
- ALDH2 | c.864del p.K289Rfs*122 | Frame Shift Del (DEL) | VAF 13/84 reads (15%) | catalogued as rs771889973, COSV55672572; called by mutect2, pindel, varscan2
- ALG1 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 33/288 reads (11%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs747642961; called by muse, mutect2, varscan2
- ALKBH8 | c.1637G>A p.R546H | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs921968873; called by muse, mutect2
- AMOT | c.2318C>T p.P773L (on ENST00000371959 / NM_001113490.1; = p.P364L on NM_133265.3) | Missense Mutation (SNP) | VAF 35/287 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as rs768234510; called by muse, mutect2, varscan2
- ANGPTL6 | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as rs754045862; called by mutect2, varscan2
- ANK2 | c.161del p.G54Afs*2 | Frame Shift Del (DEL) | VAF 20/174 reads (11%) | catalogued as COSV52197547; called by mutect2, pindel
- ANKIB1 | c.2323C>T p.R775C | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1166470234; called by muse, mutect2, varscan2
- ANO7 | c.2653C>T p.R885W (on ENST00000274979; = p.R831W on NM_001370694.2) | Missense Mutation (SNP) | VAF 38/247 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201390643; called by muse, mutect2, varscan2
- ARAP3 | c.3676C>T p.R1226W | Missense Mutation (SNP) | VAF 18/195 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1247569476; called by muse, mutect2
- AREL1 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.662); catalogued as rs763464411, COSV100707582; called by muse, mutect2, varscan2
- ARFIP2 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs1182306335, COSV99601490; called by muse, mutect2, varscan2
- ARHGAP22 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 38/350 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs761587623, COSV99985739; called by muse, mutect2, varscan2
- ARHGEF10L | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as rs575641992; called by mutect2, varscan2
- ARHGEF7 | c.565G>A p.V189I (on ENST00000375741 / NM_001113511.2; = p.V11I on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs971527897; called by muse, mutect2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 25/256 reads (10%) | catalogued as COSV61389445; called by pindel, varscan2
- ARID1B | c.5432del p.G1811Vfs*27 | Frame Shift Del (DEL) | VAF 22/153 reads (14%) | catalogued as COSV51652814; called by mutect2, pindel, varscan2
- ARRDC1 | c.1237+7C>T | Splice Region (SNP) | VAF 22/174 reads (13%) | catalogued as rs764585267; called by muse, mutect2, varscan2
- ARSA | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 39/348 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138850940; called by muse, mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 36/230 reads (16%) | catalogued as rs753865255; called by mutect2, varscan2
- ASH1L | c.2134del p.R712Efs*23 | Frame Shift Del (DEL) | VAF 20/129 reads (16%) | catalogued as rs1558150870; called by mutect2, varscan2
- ATF6B | c.1999C>T p.R667* | Nonsense Mutation (SNP) | VAF 20/170 reads (12%) | catalogued as rs771117606, COSV64351345; called by muse, mutect2, varscan2
- ATP13A3 | c.3079del p.W1027Gfs*31 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | catalogued as rs746602775; called by mutect2, varscan2
- ATXN2 | c.1442G>A p.R481H (on ENST00000550104; = p.R321H on NM_002973.4) | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs571677082; called by muse, mutect2, varscan2
- B3GALT1 | c.446A>G p.Y149C | Missense Mutation (SNP) | VAF 13/219 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs955064935; called by muse, mutect2
- B3GNTL1 | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 16/121 reads (13%) | catalogued as rs1415256532, COSV57949750; called by muse, mutect2, varscan2
- B4GALT4 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1314966890, COSV100785829; called by muse, mutect2, varscan2
- BACH2 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 34/378 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.058); catalogued as COSV57590197, COSV57602173; called by muse, mutect2
- BAHCC1 | c.7547G>A p.R2516H | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as rs781918369; called by muse, mutect2, varscan2
- BAIAP2 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs750986627, COSV100348674; called by muse, mutect2, varscan2
- BARHL2 | c.376del p.Q126Sfs*18 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | catalogued as rs747119215; called by mutect2, pindel, varscan2
- BAZ1A | c.1924C>T p.R642* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as COSV62410045; called by muse, mutect2, varscan2
- BCAS1 | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.301); catalogued as rs752495014, COSV65085414; called by mutect2, varscan2
- BCOR | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.185); catalogued as rs766556436, COSV60702798; called by muse, mutect2, varscan2
- BHLHE23 | c.328C>T p.R110W (on ENST00000370346; = p.R126W on NM_080606.4) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771988441; called by mutect2, varscan2
- BICD2 | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 47/382 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs142203302; called by muse, mutect2, varscan2
- BLVRA | c.283C>A p.L95I | Missense Mutation (SNP) | VAF 31/275 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV55515513; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 18/160 reads (11%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BNIP5 | c.1702del p.Y568Tfs*12 | Frame Shift Del (DEL) | VAF 16/145 reads (11%) | catalogued as COSV71325486; called by mutect2, pindel, varscan2
- BORCS5 | c.382_383del p.L128Vfs*86 | Frame Shift Del (DEL) | VAF 34/252 reads (13%) | catalogued as rs754957168; called by pindel, varscan2
- BPTF | c.6628G>A p.V2210I | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.206); catalogued as rs768736219; called by mutect2, varscan2
- BRPF3 | c.3428G>A p.R1143H | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV60206243, COSV60208143; called by muse, mutect2, varscan2
- BTAF1 | c.2258G>A p.R753H | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs777326643, COSV99796047; called by muse, varscan2
- BTK | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 41/379 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as rs868978699, COSV58117932; called by muse, mutect2, varscan2
- BUB1 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.932); catalogued as rs759283101, COSV57062866; called by muse, mutect2, varscan2
- C16orf46 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 17/115 reads (15%) | catalogued as COSV100215402, COSV55153182; called by muse, mutect2, varscan2
- C17orf98 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 29/199 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766541161; called by muse, mutect2, varscan2
- C6orf132 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.1); catalogued as rs1213909019; called by muse, mutect2, varscan2
- CABP5 | c.433del p.R145Gfs*24 | Frame Shift Del (DEL) | VAF 14/85 reads (16%) | catalogued as rs769959570, COSV99506527; called by mutect2, pindel, varscan2
- CACNA1G | c.2239C>T p.R747W | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1325957381; called by muse, mutect2
- CACNA1I | c.2978G>A p.S993N | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs762429765; called by muse, mutect2, varscan2
- CALD1 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs142583902; called by mutect2, varscan2
- CALHM4 | c.143del p.N48Ifs*14 | Frame Shift Del (DEL) | VAF 42/353 reads (12%) | catalogued as rs1562364010; called by mutect2, pindel, varscan2
- CALM1 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as rs751143097, COSV63662648; called by muse, mutect2, varscan2
- CARD6 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); catalogued as rs113160122; called by muse, mutect2
- CASP8AP2 | c.4423G>A p.A1475T | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1226413536; called by muse, mutect2, varscan2
- CC2D1A | c.2374G>T p.E792* | Nonsense Mutation (SNP) | VAF 30/159 reads (19%) | catalogued as COSV54307925; called by muse, mutect2, varscan2
- CCDC106 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 32/248 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.927); catalogued as rs11558497; called by muse, mutect2, varscan2
- CCDC138 | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs763016292, COSV54567381; called by mutect2, varscan2
- CCDC151 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs112797378; called by muse, mutect2, varscan2
- CCDC168 | c.3228del p.K1076Nfs*14 | Frame Shift Del (DEL) | VAF 20/142 reads (14%) | catalogued as rs765903699; called by mutect2, varscan2
- CCDC170 | c.969C>G p.Y323* | Nonsense Mutation (SNP) | VAF 29/242 reads (12%) | catalogued as rs765566316; called by muse, mutect2, varscan2
- CCDC27 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1179429043; called by muse, mutect2
- CDC23 | c.386del p.K129Rfs*10 | Frame Shift Del (DEL) | VAF 7/61 reads (11%) | catalogued as rs1561636253; called by mutect2, pindel, varscan2
- CDCP1 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 36/254 reads (14%) | catalogued as rs200941796; called by muse, mutect2, varscan2
- CDH16 | c.1686del p.K563Sfs*22 | Frame Shift Del (DEL) | VAF 26/175 reads (15%) | catalogued as rs776664434; called by mutect2, pindel, varscan2
- CDH18 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as COSV56951035; called by muse, mutect2
- CDH19 | c.1869del p.K623Nfs*34 | Frame Shift Del (DEL) | VAF 11/81 reads (14%) | catalogued as COSV50954441; called by mutect2, pindel, varscan2
- CDH4 | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 38/294 reads (13%) | catalogued as rs766529605, COSV104422525; called by muse, mutect2, varscan2
- CELSR2 | c.4060G>A p.D1354N | Missense Mutation (SNP) | VAF 39/350 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs779714491, COSV54773015; called by muse, mutect2
- CENPJ | c.2921G>A p.R974H | Missense Mutation (SNP) | VAF 54/341 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759234098; called by muse, mutect2, varscan2
- CHD6 | c.2428C>T p.R810C | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs369595632; called by muse, mutect2, varscan2
- CHRNE | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.423); catalogued as rs1415632464; called by muse, mutect2, varscan2
- CHST3 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 56/494 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs898835385, CM105995; called by mutect2, varscan2
- CHST6 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 21/289 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM002583, CM100765, COSV60000509; called by muse, mutect2
- CIZ1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1404137822, COSV99477007; called by muse, mutect2
- CKLF | c.447del p.E150Kfs*? (on ENST00000264001 / NM_016951.4; = p.E65Kfs*? on NM_016326.3) | Frame Shift Del (DEL) | VAF 34/233 reads (15%) | catalogued as rs754415052; called by mutect2, varscan2
- CLIP3 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs1227733550, COSV62112931; called by muse, mutect2, varscan2
- CNPPD1 | c.1128del p.W377Gfs*36 | Frame Shift Del (DEL) | VAF 8/100 reads (8%) | catalogued as rs764842458; called by mutect2, pindel
- CNTN1 | c.2597C>T p.A866V | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.794); catalogued as COSV61635878; called by muse, mutect2, varscan2
- COG3 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747042102, COSV63071192; called by muse, mutect2, varscan2
- COIL | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs375805743; called by muse, mutect2, varscan2
- COL18A1 | c.3448G>A p.A1150T (on ENST00000359759 / NM_130444.3; = p.A915T on NM_030582.4) | Missense Mutation (SNP) | VAF 40/315 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs372137898, COSV100645012; called by muse, mutect2, varscan2
- COL1A1 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 34/309 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs764594515; called by muse, mutect2, varscan2
- CORO2B | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 25/284 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs946241969, COSV99962949; called by muse, mutect2
- CPZ | c.718G>A p.E240K (on ENST00000360986 / NM_001014447.3; = p.E229K on NM_003652.3) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs751651131; called by mutect2, varscan2
- CPZ | c.1189del p.Q397Rfs*28 (on ENST00000360986 / NM_001014447.3; = p.Q386Rfs*28 on NM_003652.3) | Frame Shift Del (DEL) | VAF 16/164 reads (10%) | catalogued as rs1313084590, COSV100248886; called by mutect2, pindel
- CRYAB | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 31/300 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs534473091; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSDC2 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV53447926; called by muse, mutect2
- CTNNB1 | c.1628C>T p.A543V | Missense Mutation (SNP) | VAF 44/388 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV62711368; called by muse, mutect2, varscan2
- CUL9 | c.3935G>A p.R1312H | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as rs376267285; called by muse, mutect2
- DAB1 | c.1105del p.A369Lfs*132 (on ENST00000371231; = p.A336Lfs*132 on NM_021080.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 19/168 reads (11%) | catalogued as COSV64693748; called by mutect2, pindel, varscan2
- DAB2IP | c.39C>T p.Y13= | Splice Region (SNP) | VAF 16/109 reads (15%) | catalogued as rs201252302, COSV52255139; called by muse, mutect2, varscan2
- DAB2IP | c.395G>A p.R132H (on ENST00000408936; = p.R104H on NM_032552.3) | Missense Mutation (SNP) | VAF 31/251 reads (12%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.987); catalogued as rs201767314, COSV52263928; called by muse, mutect2, varscan2
- DBF4B | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as rs1174953645, COSV100154506; called by muse, mutect2
- DCAF5 | c.2506C>T p.R836C | Missense Mutation (SNP) | VAF 30/313 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs145198076; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX51 | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 29/276 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs376428090; called by muse, mutect2
- DENND4B | c.22del p.R8Gfs*8 | Frame Shift Del (DEL) | VAF 15/152 reads (10%) | catalogued as rs755611865; called by mutect2, pindel, varscan2
- DGKI | c.337_339del p.E113del | In Frame Del (DEL) | VAF 5/48 reads (10%) | catalogued as rs766543557; called by mutect2, pindel, varscan2
- DHX34 | c.2674C>A p.L892M | Missense Mutation (SNP) | VAF 49/251 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs752951624; called by muse, mutect2, varscan2
- DLG4 | c.1474C>T p.R492W (on ENST00000399506 / NM_001321075.3; = p.R535W on NM_001365.4) | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57242000; called by muse, mutect2, varscan2
- DLGAP3 | c.254del p.G85Vfs*215 | Frame Shift Del (DEL) | VAF 18/142 reads (13%) | catalogued as rs762874947; called by mutect2, varscan2
- DLX3 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 23/239 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101460580, COSV71547576; called by muse, mutect2, varscan2
- DNAH1 | c.8237C>T p.P2746L | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs548600793, COSV70226879; called by muse, mutect2, varscan2
- DNAH17 | c.10072C>T p.L3358F | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101101937; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 14/124 reads (11%) | catalogued as rs782552436; called by mutect2, varscan2
- DPYS | c.1090G>A p.V364M | Missense Mutation (SNP) | VAF 37/347 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs138282507, CM102075; called by muse, mutect2, varscan2
- DTL | c.1432T>C p.S478P | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.322); catalogued as rs982647322; called by muse, mutect2
- DYNC1H1 | c.5411G>A p.R1804Q | Missense Mutation (SNP) | VAF 65/522 reads (12%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.924); catalogued as rs746543001, COSV64134410; called by muse, mutect2, varscan2
- EBF3 | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV100799510, COSV62476347; called by muse, mutect2, varscan2
- ENPP6 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs763550965, COSV57067778, COSV57073880; called by muse, mutect2, varscan2
- EP400 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs1172065003, COSV57761858; called by muse, mutect2, varscan2
- ERBIN | c.4043G>A p.R1348K (on ENST00000284037 / NM_001253697.2; = p.R1307K on NM_018695.4) | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.89); PolyPhen benign (0.015); catalogued as COSV99397512; called by muse, mutect2
- ERICH6B | c.950dup p.E318Gfs*10 | Frame Shift Ins (INS) | VAF 28/178 reads (16%) | catalogued as rs754232917; called by mutect2, varscan2
- ETNK2 | c.790G>A p.V264M | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs374969247; called by muse, mutect2, varscan2
- ETV3 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs1343103303, COSV63864755; called by muse, mutect2
- FAM171A1 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as rs184600985; called by mutect2, varscan2
- FAM210A | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.183); catalogued as rs552796973, COSV59183362; called by mutect2, varscan2
- FAM214A | c.1444C>T p.R482W | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760620517; called by muse, mutect2, varscan2
- FAT3 | c.11333G>A p.R3778H | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as rs368636238; called by muse, mutect2, varscan2
- FAT4 | c.5462A>G p.Q1821R | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1263081787; called by muse, mutect2
- FBLN5 | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 65/624 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0.05); catalogued as rs747580479; called by mutect2, varscan2
- FBXL18 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66107583; called by muse, mutect2, varscan2
- FBXO10 | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 31/257 reads (12%) | catalogued as rs1436728936, COSV99447322; called by muse, mutect2, varscan2
- FCGR2A | c.38C>A p.P13H | Missense Mutation (SNP) | VAF 10/205 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.839); catalogued as COSV54837700; called by muse, mutect2
- FCRL5 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as rs754564708; called by mutect2, varscan2
- FGF23 | c.329C>A p.P110Q | Missense Mutation (SNP) | VAF 61/541 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.115); catalogued as rs773591533, COSV52975735, COSV99426376; called by muse, mutect2, varscan2
- FGF3 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.109); catalogued as rs1156753470, COSV61926245; called by muse, mutect2
- FHL5 | c.186G>A p.W62* | Nonsense Mutation (SNP) | VAF 9/84 reads (11%) | catalogued as rs1231216391; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FKBP9 | c.384del p.N129Ifs*10 | Frame Shift Del (DEL) | VAF 18/166 reads (11%) | catalogued as rs752076602; called by mutect2, pindel
- FLAD1 | c.1546C>T p.P516S | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1247583486; called by muse, mutect2, varscan2
- FLNA | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 87/656 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1287150584; called by muse, varscan2
- FLT4 | c.2957C>T p.S986L | Missense Mutation (SNP) | VAF 36/270 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV56119167; called by muse, mutect2, varscan2
- FMN1 | c.3419G>A p.R1140H (on ENST00000616417 / NM_001277313.2; = p.R917H on NM_001103184.4) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367950025; called by muse, mutect2, varscan2
- FNBP4 | c.2721_2726del p.P917_P918del | In Frame Del (DEL) | VAF 7/46 reads (15%) | catalogued as rs762287139; called by mutect2, varscan2
- FNDC8 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.204); catalogued as rs139338261; called by muse, mutect2, varscan2
- FOXJ3 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs149676672; called by muse, mutect2, varscan2
- FRMD1 | c.1427G>T p.G476V | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.218); catalogued as COSV51962055; called by muse, mutect2
- G6PD | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 53/403 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs979416826, CM970547, COSV63703425, COSV63703740; called by muse, mutect2, varscan2
- GABRA6 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs954355576; called by muse, mutect2
- GDF1 | c.933del p.P312Rfs*73 | Frame Shift Del (DEL) | VAF 4/45 reads (9%) | catalogued as rs1213194580; called by pindel, varscan2
- GGA2 | c.1571C>T p.T524M | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs756592274; called by mutect2, varscan2
- GIMAP8 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs200592029, COSV56232852, COSV56235726; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 17/123 reads (14%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GLIS2 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 19/398 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1287524266, COSV52109238; called by muse, mutect2
- GNL3L | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.189); catalogued as rs758691564; called by muse, mutect2, varscan2
- GNPDA1 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs370128744; called by muse, mutect2, varscan2
- GON4L | c.5332C>T p.R1778C | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs372943625; called by muse, mutect2, varscan2
- GPC1 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 21/227 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as rs761559309; called by muse, mutect2
- GPR37L1 | c.928A>G p.M310V | Missense Mutation (SNP) | VAF 47/329 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs778030980; called by muse, mutect2, varscan2
- GRIK5 | c.1417G>A p.G473R | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1181684922, COSV99491283; called by muse, mutect2
- GRIN2B | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.726); catalogued as rs201377003, COSV74205072; ClinVar: likely benign; called by muse, mutect2
- GRIPAP1 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.997); catalogued as rs1464612429, COSV100904359; called by muse, mutect2, varscan2
- GSDMA | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 31/279 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs767159876; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1759G>A p.V587I | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as rs781842329, COSV56088897; called by muse, mutect2
- GTF2IRD2B | c.1702C>T p.R568C | Missense Mutation (SNP) | VAF 16/470 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs782149057, COSV100441306; called by muse, mutect2
- H1-4 | c.540G>T p.K180N | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.207); catalogued as COSV56799599; called by muse, mutect2, varscan2
- HAUS3 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1307185528; called by muse, mutect2
- HDGFL2 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1297892451, COSV56683912; called by muse, mutect2
- HEATR5B | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs1348780312, COSV51848963; called by muse, mutect2, varscan2
- HECTD4 | c.8069G>A p.R2690H | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1422284330, COSV66393273; called by muse, mutect2
- HELB | c.2488G>A p.V830I | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as rs755181246; called by muse, mutect2, varscan2
- HELZ2 | c.3641G>A p.R1214H (on ENST00000467148 / NM_001037335.2; = p.R645H on NM_033405.3) | Missense Mutation (SNP) | VAF 34/297 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs769920759; called by muse, mutect2, varscan2
- HEPHL1 | c.3276C>T p.N1092= | Splice Region (SNP) | VAF 23/161 reads (14%) | catalogued as rs560509955, COSV100243839, COSV59889234; called by muse, mutect2, varscan2
- HERC2 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs777222189; called by muse, mutect2, varscan2
- HIPK1 | c.3160G>A p.A1054T (on ENST00000369558 / NM_001369806.1; = p.A660T on NM_181358.2) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1239465633, COSV61246149; called by muse, mutect2
- HMCN1 | c.13214C>T p.A4405V | Missense Mutation (SNP) | VAF 13/224 reads (6%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.995); catalogued as rs1306049718; called by muse, mutect2
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | catalogued as rs767148651; called by mutect2, varscan2
- HNRNPUL2 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.522); catalogued as rs749881089; called by muse, mutect2, varscan2
- HSPA8 | c.1361A>G p.N454S | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.077); catalogued as COSV57084162; called by muse, mutect2
- HTT | c.1618G>A p.V540I | Missense Mutation (SNP) | VAF 52/431 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as rs747431001, COSV100751018; called by muse, mutect2, varscan2
- HUNK | c.1816G>A p.G606R | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as rs539652834; called by muse, mutect2
- HUWE1 | c.8840C>T p.P2947L | Missense Mutation (SNP) | VAF 57/407 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53337017; called by muse, mutect2, varscan2
- HYDIN | c.5503C>G p.P1835A | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV59252697; called by muse, mutect2, varscan2
- IGFBP1 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV51875150; called by muse, mutect2, varscan2
- IL11RA | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 64/571 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs753271645, COSV52404783; called by muse, mutect2, varscan2
- IL18RAP | c.87del p.K29Nfs*66 | Frame Shift Del (DEL) | VAF 10/87 reads (11%) | catalogued as rs756319084; called by mutect2, pindel, varscan2
- IL3RA | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as rs1372137893; called by muse, mutect2, varscan2
- IL7R | c.518del p.K173Rfs*9 | Frame Shift Del (DEL) | VAF 16/178 reads (9%) | catalogued as COSV100286374; called by mutect2, pindel
- IMP4 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 50/378 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs775723557, COSV99383872; called by muse, mutect2, varscan2
- INSM2 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV99354562; called by muse, mutect2
- IP6K1 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 20/478 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1559700395; called by muse, mutect2
- IQCH | c.2663C>T p.A888V | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs142903968; called by mutect2, varscan2
- IREB2 | c.2353G>A p.G785R | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51920853; called by muse, mutect2
- ITGAE | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs1372387842; called by muse, mutect2, varscan2
- ITGB1BP2 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs1459999811; called by muse, mutect2, varscan2
- ITPRIP | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs764102033, COSV53391507; called by muse, mutect2, varscan2
- JRK | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs782289704, COSV70629728; called by muse, mutect2
- KANSL1 | c.3017G>A p.R1006Q (on ENST00000574590 / NM_001193465.2; = p.R1007Q on NM_015443.4) | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs148203818; called by muse, mutect2, varscan2
- KAT6B | c.1718G>A p.R573H | Missense Mutation (SNP) | VAF 38/364 reads (10%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); catalogued as rs1404119097, COSV99767678; called by muse, mutect2
- KCND2 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752601891, COSV58600481; called by muse, mutect2
- KCNJ13 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs1293854136; called by muse, mutect2, varscan2
- KCNK1 | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs139235616; called by muse, mutect2
- KDM2B | c.3574C>T p.R1192W | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs372338495; called by muse, mutect2
- KDM5B | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 9/71 reads (13%) | catalogued as rs756616242, COSV52505933; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIAA0319L | c.3134G>A p.R1045Q | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs373199789, COSV57849669; called by muse, mutect2, varscan2
- KIAA0319L | c.399dup p.F134Ifs*6 | Frame Shift Ins (INS) | VAF 19/176 reads (11%) | catalogued as rs1383796563; called by mutect2, varscan2
- KLF3 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV54710504; called by muse, mutect2, varscan2
- KMT2B | c.6482G>A p.R2161H | Missense Mutation (SNP) | VAF 41/225 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as rs747873093, COSV55865272; called by muse, mutect2, varscan2
- LANCL3 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 28/287 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.084); catalogued as rs1556415519; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 15/68 reads (22%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LBX2 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 43/277 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1187448376; called by muse, mutect2, varscan2
- LHX3 | c.550C>T p.R184C (on ENST00000371748 / NM_178138.6; = p.R189C on NM_014564.5) | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1045386522; called by muse, mutect2, varscan2
- LIMCH1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs747038179; called by muse, mutect2, varscan2
- LMO7 | c.2114G>A p.R705H (on ENST00000357063; = p.R386H on NM_005358.5) | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as rs760276700; called by muse, mutect2, varscan2
- LOXHD1 | c.4921G>A p.A1641T | Missense Mutation (SNP) | VAF 17/238 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as rs914109134, COSV56067682; called by muse, mutect2
- LOXL2 | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.105); catalogued as rs142220945; called by muse, mutect2, varscan2
- LPAR3 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1430003017; called by muse, mutect2, varscan2
- LRCH4 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs777783218, COSV100053250; called by muse, mutect2, varscan2
- LRFN1 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 96/409 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs1023018556, COSV50501112; called by muse, mutect2, varscan2
- LRFN2 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.348); catalogued as rs140980612; called by muse, mutect2
- LRP4 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 38/542 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101066422, COSV101066908; called by muse, mutect2
- LRP6 | c.2798C>T p.T933M | Missense Mutation (SNP) | VAF 30/281 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.418); catalogued as rs772208806, COSV53795981; called by muse, mutect2, varscan2
- LRRC8D | c.626C>T p.T209M | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61580857; called by muse, mutect2
- LRRK2 | c.4915del p.R1639Gfs*15 | Frame Shift Del (DEL) | VAF 11/84 reads (13%) | catalogued as rs756089224; called by mutect2, varscan2
- LTBP2 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 49/296 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs574843979; called by muse, mutect2, varscan2
- MAST3 | c.3716G>A p.R1239Q | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.053); catalogued as rs1033338534; called by muse, mutect2, varscan2
- MCOLN1 | c.594del p.E199Sfs*39 | Frame Shift Del (DEL) | VAF 41/333 reads (12%) | catalogued as rs1349755445, COSV51177134; called by mutect2, varscan2
- MED17 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 46/398 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs760044024; called by muse, mutect2
- MEGF8 | c.6428dup p.Q2144Pfs*17 (on ENST00000251268 / NM_001271938.2; = p.Q2077Pfs*17 on NM_001410.3) | Frame Shift Ins (INS) | VAF 13/92 reads (14%) | catalogued as rs1258909672; called by mutect2, varscan2
- MEIOB | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as rs372655502; called by muse, mutect2, varscan2
- MFSD2A | c.1016G>A p.R339H (on ENST00000372809 / NM_001136493.3; = p.R326H on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.985); catalogued as rs776741331, COSV65684977; called by muse, mutect2, varscan2
- MICALL2 | c.1416C>T p.G472= | Splice Region (SNP) | VAF 10/144 reads (7%) | catalogued as rs1489373218; called by muse, mutect2
- MID1 | c.1927G>A p.V643M | Missense Mutation (SNP) | VAF 36/311 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1198220434, COSV58198433; called by muse, mutect2, varscan2
- MINK1 | c.1118A>T p.Q373L | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as rs770761556; called by mutect2, varscan2
- MN1 | c.3556G>A p.A1186T | Missense Mutation (SNP) | VAF 31/264 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs753939819, COSV56558178; called by muse, mutect2, varscan2
- MPHOSPH10 | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 17/90 reads (19%) | catalogued as COSV54914326; called by muse, mutect2, varscan2
- MRC2 | c.4330C>T p.R1444C | Missense Mutation (SNP) | VAF 37/293 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs567602213; called by muse, mutect2, varscan2
- MTAP | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs751881433; called by muse, mutect2, varscan2
- MTMR10 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as rs775743665, COSV58729195; called by muse, mutect2, varscan2
- MTMR9 | c.584del p.N195Mfs*4 | Frame Shift Del (DEL) | VAF 12/84 reads (14%) | catalogued as rs767880823; called by mutect2, varscan2
- MTRR | c.715G>A p.V239M (on ENST00000264668; = p.V212M on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/470 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.288); catalogued as COSV52941425; called by muse, mutect2
- MUC1 | c.2860G>A p.A954T (on ENST00000611571 / NM_001371720.1; = p.A167T on NM_001204285.2) | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.625); catalogued as rs772887466; called by muse, mutect2, varscan2
- MUC5B | c.14552C>T p.P4851L | Missense Mutation (SNP) | VAF 56/404 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs201730803; called by mutect2, varscan2
- MUC6 | c.3118G>A p.V1040M | Missense Mutation (SNP) | VAF 52/451 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as rs573979427; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 40/143 reads (28%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYH7 | c.5537G>A p.R1846H | Missense Mutation (SNP) | VAF 36/448 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs757803046; ClinVar: uncertain significance; called by muse, mutect2
- MYO1C | c.2401del p.R801Afs*18 (on ENST00000648651 / NM_001080779.2; = p.R766Afs*18 on NM_033375.5) | Frame Shift Del (DEL) | VAF 11/103 reads (11%) | catalogued as rs1446133378; called by mutect2, pindel
- NAA25 | c.2135C>T p.S712L | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs751642260, COSV55708859; called by muse, mutect2, varscan2
- NAAA | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs777433295, COSV54432217; called by muse, mutect2, varscan2
- NAAA | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1175742430; called by muse, mutect2, varscan2
- NAPEPLD | c.842del p.F281Sfs*14 | Frame Shift Del (DEL) | VAF 20/142 reads (14%) | catalogued as rs746683932, COSV100439928; called by mutect2, varscan2
- NAV1 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV55225800; called by muse, varscan2
- NBEA | c.142del p.A48Rfs*7 | Frame Shift Del (DEL) | VAF 8/82 reads (10%) | catalogued as COSV59783949; called by mutect2, pindel
- NCDN | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 53/402 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as rs1326831347, COSV57844623, COSV57851383; called by muse, mutect2, varscan2
- NCOR2 | c.3968C>T p.S1323F | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs570066332; called by muse, mutect2, varscan2
- NDUFA9 | c.884T>C p.L295P | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.055); catalogued as COSV99866225; called by muse, mutect2
- NFATC1 | c.605C>T p.T202M | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs759719115, COSV53697149; called by muse, mutect2, varscan2
- NIBAN1 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs542303174, COSV62287892; called by muse, mutect2
- NIBAN3 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV56305655; called by muse, mutect2
- NIPBL | c.3202C>T p.R1068C | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs762234061; called by muse, mutect2
- NKPD1 | c.2332del p.H778Tfs*98 | Frame Shift Del (DEL) | VAF 39/236 reads (17%) | catalogued as rs777176845; called by mutect2, pindel, varscan2
- NLRP5 | c.2918G>A p.R973Q | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.056); catalogued as rs199737074; called by muse, mutect2, varscan2
- NOL12 | c.385G>T p.G129W | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV63031153; called by muse, mutect2
- NOP14 | c.2473C>T p.R825W | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs144192491; called by muse, varscan2
- NR1H3 | c.601del p.Q201Kfs*13 | Frame Shift Del (DEL) | VAF 22/193 reads (11%) | catalogued as rs779801455; called by mutect2, pindel, varscan2
- NR5A1 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376558631, CM108777; called by muse, mutect2, varscan2
- NR5A1 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 45/334 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1253324106, CM106615, COSV65295278; called by muse, mutect2, varscan2
- NUDT1 | c.31del p.E11Sfs*35 | Frame Shift Del (DEL) | VAF 14/105 reads (13%) | catalogued as rs1186040683; called by mutect2, pindel, varscan2
- NUP205 | c.5384C>T p.P1795L | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as rs372734141; called by muse, mutect2, varscan2
- NXF1 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 16/131 reads (12%) | catalogued as rs772149198, COSV53673446; called by muse, mutect2, varscan2
- OCA2 | c.1841del p.K614Sfs*14 | Frame Shift Del (DEL) | VAF 30/140 reads (21%) | catalogued as CD000269; called by mutect2, varscan2
- OGN | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV99364310; called by muse, mutect2, varscan2
- OLFML2A | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs188129436, COSV56582761; called by muse, mutect2, varscan2
- OR52A5 | c.224T>G p.L75R | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100263279, COSV56615171; called by muse, mutect2
- OR8I2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 32/285 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs561919245, COSV56169726, COSV56170425; called by muse, mutect2
- OTOGL | c.4763del p.K1588Sfs*2 (on ENST00000547103; = p.K1579Sfs*2 on NM_173591.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 9/63 reads (14%) | catalogued as rs1375960265; called by mutect2, pindel*, varscan2
- OTUD4 | c.2866G>A p.V956I (on ENST00000447906 / NM_001366057.1; = p.V891I on NM_001102653.1) | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as rs1433024612; called by muse, mutect2
- PARP11 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs778761342; called by mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 36/342 reads (11%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PBX2 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1239874793; called by muse, mutect2, varscan2
- PCDH17 | c.2565+1G>C p.X855_splice | Splice Site (SNP) | VAF 9/103 reads (9%) | catalogued as COSV64979264; called by muse, mutect2
- PCDHA11 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 11/298 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56480358, COSV56484098; called by muse, mutect2
- PCDHA3 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 50/850 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.135); catalogued as rs190722768, COSV63538704; called by muse, mutect2
- PCDHB11 | c.1267G>A p.V423I | Missense Mutation (SNP) | VAF 16/370 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.403); catalogued as COSV61309711; called by muse, mutect2
- PCDHGA6 | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.018); catalogued as COSV53894469; called by muse, varscan2
- PCDHGB4 | c.1675C>T p.R559W | Missense Mutation (SNP) | VAF 55/508 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1388057704, COSV53910946; called by muse, mutect2, varscan2
- PCID2 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.041); catalogued as rs375098990; called by muse, mutect2, varscan2
- PDC | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.988); catalogued as rs753963861, COSV60853834; called by muse, mutect2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs759495724; called by mutect2, varscan2
- PDZRN3 | c.2294G>A p.R765H | Missense Mutation (SNP) | VAF 30/303 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1264714719, COSV55206860; called by muse, mutect2
- PGBD1 | c.2005dup p.M669Nfs*7 | Frame Shift Ins (INS) | VAF 24/206 reads (12%) | catalogued as rs781166611; called by mutect2, varscan2
- PGBD1 | c.2062C>T p.R688C | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs747908172, COSV99459991; called by muse, mutect2, varscan2
- PHACTR1 | c.1631G>A p.R544H | Missense Mutation (SNP) | VAF 57/404 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1304744795; called by muse, mutect2, varscan2
- PHACTR2 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs566532922, COSV59855684; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 14/98 reads (14%) | catalogued as rs769717544; called by mutect2, varscan2
- PHRF1 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 34/303 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs566767012; called by muse, mutect2, varscan2
- PHYKPL | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs761596988; called by muse, mutect2, varscan2
- PIP5K1A | c.887del p.L296Wfs*25 (on ENST00000368888 / NM_001135638.2; = p.L283Wfs*25 on NM_003557.3) | Frame Shift Del (DEL) | VAF 23/203 reads (11%) | catalogued as rs756244757; called by mutect2, pindel
- PKHD1 | c.6120C>T p.H2040= | Splice Region (SNP) | VAF 34/373 reads (9%) | catalogued as rs747414274, COSV100582986; called by muse, mutect2
- PKP4 | c.2857G>A p.A953T | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.913); catalogued as COSV61580984; called by muse, mutect2, varscan2
- PLAAT4 | c.483del p.A162Rfs*56 | Frame Shift Del (DEL) | VAF 14/77 reads (18%) | catalogued as rs745860467; called by mutect2, varscan2
- PLCH1 | c.4489G>A p.D1497N (on ENST00000340059 / NM_001130960.2; = p.D1489N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/320 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774216828, COSV58209719; called by muse, mutect2, varscan2
- PLEKHG3 | c.2900G>A p.S967N (on ENST00000394691; = p.S1023N on NM_001308147.2) | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99906877; called by muse, mutect2, varscan2
- PLIN3 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs371377226; called by muse, mutect2
- PLOD1 | c.1387C>T p.R463W | Missense Mutation (SNP) | VAF 45/377 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs745946511; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLOD3 | c.1127+7G>A | Splice Region (SNP) | VAF 37/341 reads (11%) | catalogued as rs758089993; called by muse, mutect2, varscan2
- PLVAP | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 34/255 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1297171103, COSV53084896; called by muse, mutect2, varscan2
- PLXNA4 | c.4147C>T p.R1383C | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs888077375; called by muse, mutect2, varscan2
- POLE | c.2091dup p.F699Vfs*11 | Frame Shift Ins (INS) | VAF 10/68 reads (15%) | catalogued as rs752846614; ClinVar: uncertain significance; called by mutect2, varscan2
- POLQ | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV51756190; called by muse, mutect2
- POM121 | c.2983T>C p.F995L (on ENST00000434423; = p.F730L on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.206); catalogued as rs782811115; called by muse, mutect2
- PPAN-P2RY11 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as COSV99460788; called by muse, mutect2
- PPEF1 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.28); catalogued as rs199971323; called by muse, mutect2, varscan2
- PPFIA2 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.989); catalogued as rs377428808, COSV61030740; called by muse, mutect2, varscan2
- PPM1G | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.169); catalogued as COSV100641889; called by muse, mutect2, varscan2
- PPP1R10 | c.2815dup p.L939Pfs*62 | Frame Shift Ins (INS) | VAF 16/130 reads (12%) | catalogued as rs750124216; called by mutect2, varscan2
- PPP1R13B | c.3133G>A p.A1045T | Missense Mutation (SNP) | VAF 48/449 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs775624271, COSV52453229; called by muse, mutect2, varscan2
- PPP1R13L | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs1248331159; called by muse, mutect2, varscan2
- PPP1R36 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.495); catalogued as rs78726030, COSV100073058; called by mutect2, varscan2
- PPP1R3F | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1557118799; called by muse, mutect2, varscan2
- PPP4R4 | c.1663C>T p.R555C | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748941064; called by muse, mutect2, varscan2
- PRAM1 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV99725260; called by muse, mutect2
- PRKDC | c.4165G>A p.V1389I | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1445022618, COSV58045913; called by muse, mutect2
- PRR35 | c.1372G>A p.V458M | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as rs376789660; called by muse, mutect2, varscan2
- PRRC2A | c.2698C>T p.R900* | Nonsense Mutation (SNP) | VAF 12/70 reads (17%) | catalogued as rs1464925342, COSV101051305; called by muse, mutect2, varscan2
- PSD4 | c.569C>T p.T190M | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as rs368039539; called by muse, mutect2, varscan2
- PSG3 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 58/294 reads (20%) | catalogued as rs771778877, COSV59502250, COSV59504058; called by mutect2, varscan2
- PSMB11 | c.740A>G p.E247G | Missense Mutation (SNP) | VAF 27/226 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1219637490; called by muse, mutect2, varscan2
- PTPRG | c.2117G>A p.R706Q | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs753382729; called by muse, mutect2, varscan2
- PTPRU | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as rs759835384; called by mutect2, varscan2
- R3HDM4 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs373665929; called by muse, mutect2, varscan2
- RAX | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs1430587459; called by muse, mutect2
- RCOR2 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 59/486 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs750567813; called by muse, mutect2, varscan2
- RELL1 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 38/319 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs537739174, COSV58450566; called by muse, mutect2, varscan2
- REN | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 67/560 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs760985112, COSV65817975; called by mutect2, varscan2
- RFX8 | c.774G>T p.K258N (on ENST00000646446; = p.K187N on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65178711; called by muse, mutect2, varscan2
- RGMA | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 29/291 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.897); catalogued as rs762713342, COSV61233911; called by muse, mutect2, varscan2
- RGSL1 | c.2444G>A p.R815H | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as rs1215402820, COSV54260972; called by muse, mutect2
- RIN2 | c.1082C>T p.P361L (on ENST00000255006 / NM_001242581.1; = p.P312L on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs368837181; called by muse, mutect2, varscan2
- RNF123 | c.1629+1del | Frame Shift Del (DEL) | VAF 28/252 reads (11%) | catalogued as COSV59688684; called by mutect2, varscan2
- ROBO3 | c.3400G>A p.V1134I | Missense Mutation (SNP) | VAF 34/269 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as rs770227010; called by muse, mutect2, varscan2
- RPA3 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.065); catalogued as rs777846960; called by muse, mutect2, varscan2
- RYR1 | c.177del p.D60Ifs*58 | Frame Shift Del (DEL) | VAF 18/126 reads (14%) | catalogued as rs756326114; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- RYR2 | c.12589A>G p.I4197V | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as rs765238394; ClinVar: uncertain significance; called by muse, mutect2
- RYR3 | c.1777C>T p.R593W | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs749732234, COSV66785528, COSV66788594; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAG | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs556476934, COSV101300718; called by muse, varscan2
- SAMD3 | c.1051A>G p.R351G | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1268581241; called by muse, mutect2, varscan2
- SAMD9 | c.2363G>A p.R788H | Missense Mutation (SNP) | VAF 35/323 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780363399, COSV66073530, COSV66076252; called by muse, mutect2, varscan2
- SBF2 | c.2827C>T p.R943W | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56297436; called by muse, mutect2, varscan2
- SCAMP4 | c.-39G>A | Splice Region (SNP) | VAF 24/237 reads (10%) | catalogued as rs530153133; called by muse, mutect2
- SCD | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 57/353 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100948841; called by muse, mutect2, varscan2
- SCGB1D2 | c.199G>T p.D67Y | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55274267; called by mutect2, varscan2
- SCN5A | c.5795C>T p.A1932V (on ENST00000333535 / NM_198056.3; = p.A1931V on NM_000335.5) | Missense Mutation (SNP) | VAF 35/348 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs371194826; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SDK2 | c.2878G>A p.A960T | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as rs746767238, COSV66192341; called by muse, varscan2
- SEBOX | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs781927397, COSV52646227; called by muse, mutect2, varscan2
- SENP1 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760101961, COSV50306158; called by mutect2, varscan2
- SEPTIN2 | c.223dup p.I75Nfs*2 | Frame Shift Ins (INS) | VAF 18/166 reads (11%) | catalogued as rs758354393; called by mutect2, varscan2
- SETD1A | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs746932623; called by muse, mutect2, varscan2
- SETD1B | c.1796G>C p.G599A | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as COSV57349484; called by muse, mutect2, varscan2
- SFRP2 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs372453250; called by muse, mutect2, varscan2
- SGO2 | c.1929del p.G644Vfs*18 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | catalogued as rs1260834379; called by mutect2, varscan2
- SH2D5 | c.655C>T p.R219C (on ENST00000444387 / NM_001103161.2; = p.R135C on NM_001103160.2) | Missense Mutation (SNP) | VAF 34/228 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs759712251, COSV66706379; called by muse, mutect2, varscan2
- SH3YL1 | c.1015G>A p.V339I | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs760691492, COSV62156400; called by mutect2, varscan2
- SHANK2 | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555055747; called by muse, mutect2
- SHPRH | c.3271C>T p.R1091C (on ENST00000275233 / NM_001042683.3; = p.R1100C on NM_173082.3) | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1196713424, COSV51609071; called by muse, mutect2, varscan2
- SIPA1L1 | c.2977C>T p.R993C | Missense Mutation (SNP) | VAF 41/415 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100665167; called by muse, mutect2
- SIRT4 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.95); PolyPhen benign (0.009); catalogued as rs202219623; called by muse, varscan2
- SIX3 | c.221del p.P74Rfs*177 | Frame Shift Del (DEL) | VAF 15/115 reads (13%) | catalogued as rs760462666, COSV53226999; called by mutect2, pindel, varscan2
- SIX6 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 30/291 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1237413105, COSV59803403; called by muse, mutect2
- SKIV2L | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 23/256 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs746886184, COSV61712874; called by muse, mutect2
- SLAMF1 | c.829del p.S277Afs*54 | Frame Shift Del (DEL) | VAF 30/94 reads (32%) | catalogued as rs751442558; called by mutect2, varscan2
- SLBP | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.245); catalogued as rs777375245; called by muse, mutect2, varscan2
- SLC12A1 | c.2870T>A p.I957N | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1196278590; called by muse, mutect2
- SLC12A7 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV53755476; called by muse, mutect2, varscan2
- SLC1A7 | c.1227-6del | Splice Region (DEL) | VAF 18/188 reads (10%) | catalogued as COSV100439485; called by mutect2, pindel, varscan2
- SLC22A1 | c.70A>G p.I24V | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV61452565; called by muse, mutect2, varscan2
- SLC22A4 | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 65/412 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1198530094; called by muse, mutect2, varscan2
- SLC25A53 | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782336534; called by muse, mutect2
- SLC26A4 | c.767C>T p.T256M | Missense Mutation (SNP) | VAF 21/237 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs375279030; called by muse, mutect2
- SLC29A4 | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51877222; called by muse, mutect2, varscan2
- SLC35E4 | c.93del p.E32Sfs*97 | Frame Shift Del (DEL) | VAF 22/168 reads (13%) | catalogued as rs768838929; called by mutect2, varscan2
- SLC37A2 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as rs371217812; called by muse, mutect2, varscan2
- SLC38A5 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 29/271 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58334711; called by muse, mutect2, varscan2
- SLC4A2 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1031328236, COSV59655777; called by muse, mutect2
- SLC6A18 | c.1531C>T p.R511W | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.092); catalogued as rs376123796; called by muse, mutect2, varscan2
- SLC9A6 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs782759179, COSV65788117; called by muse, mutect2, varscan2
- SLC9A6 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1556620326, COSV65787245; called by muse, mutect2, varscan2
- SLC9B1 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 24/506 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs1174937745; called by muse, mutect2
- SLCO3A1 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs761312118, COSV100575536, COSV59234825; called by mutect2, varscan2
- SLITRK3 | c.2288A>T p.E763V | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV53849207; called by muse, mutect2
- SLTM | c.1933C>T p.R645* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | catalogued as COSV99989406; called by mutect2, varscan2
- SMARCA4 | c.3731G>A p.R1244H | Missense Mutation (SNP) | VAF 23/466 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.816); catalogued as rs1060502060, COSV60790860, COSV60794377; ClinVar: uncertain significance; called by muse, mutect2
- SMC1A | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 38/361 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs781903928; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMC3 | c.127del p.Y43Mfs*69 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | catalogued as rs1466680694; called by pindel, varscan2
- SNF8 | c.506_509del p.I169Sfs*24 | Frame Shift Del (DEL) | VAF 18/124 reads (15%) | catalogued as rs769468017; called by mutect2, pindel, varscan2
- SPACA7 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.272); catalogued as rs766125009, COSV52098010; called by muse, mutect2, varscan2
- SPAG17 | c.1414A>G p.R472G | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1377113994; called by muse, mutect2
- SPANXC | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 36/246 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs141616408; called by muse, mutect2, varscan2
- SPTA1 | c.178C>T p.R60* | Nonsense Mutation (SNP) | VAF 24/322 reads (7%) | catalogued as rs373695294; called by muse, mutect2
- SRCAP | c.6536del p.K2179Rfs*128 | Frame Shift Del (DEL) | VAF 14/98 reads (14%) | catalogued as COSV52675361; called by mutect2, varscan2
- SRRM2 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 32/280 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs370490379; called by muse, mutect2, varscan2
- STARD13 | c.1406C>T p.A469V (on ENST00000336934 / NM_001243476.3; = p.A351V on NM_052851.3) | Missense Mutation (SNP) | VAF 50/386 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as rs1313848334; called by muse, mutect2, varscan2
- STARD13 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs539950672; called by muse, mutect2, varscan2
- STAT3 | c.158C>G p.A53G | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52885539; called by muse, mutect2
- STIL | c.3363del p.K1121Nfs*3 | Frame Shift Del (DEL) | VAF 17/125 reads (14%) | catalogued as COSV99680901; called by mutect2, pindel, varscan2
- STK32C | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 30/257 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as rs764558009, COSV53837850; called by muse, mutect2, varscan2
- STK35 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); catalogued as rs776552962; called by mutect2, varscan2
- STOM | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs753860952; called by mutect2, varscan2
- STX5 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs761425627, COSV99586266; called by muse, mutect2, varscan2
- STYXL2 | c.1822G>A p.V608M | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs1468803310; called by muse, mutect2, varscan2
- SUN2 | c.2040+5G>A | Splice Region (SNP) | VAF 36/302 reads (12%) | catalogued as rs781734474; called by muse, mutect2, varscan2
- SYNE2 | c.6746G>A p.R2249Q | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764036360, COSV59949364; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAGAP | c.1420G>A p.V474M | Missense Mutation (SNP) | VAF 28/261 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs762949562; called by muse, mutect2, varscan2
- TANGO6 | c.2744C>T p.P915L | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs750201074; called by muse, mutect2, varscan2
- TAS1R3 | c.255_257del p.N85del | In Frame Del (DEL) | VAF 34/283 reads (12%) | catalogued as rs753370478; called by pindel, varscan2
- TASP1 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); catalogued as rs1464881790, COSV61812992; called by muse, mutect2, varscan2
- TATDN2 | c.1432G>A p.A478T | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs557665159, COSV55050994; called by muse, mutect2
- TBC1D20 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as rs368269156; called by muse, mutect2, varscan2
- TBC1D9B | c.2234C>T p.P745L | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as rs574944861; called by muse, mutect2, varscan2
- TBX1 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 40/358 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1294927055, COSV100226482; called by muse, mutect2, varscan2
- TCAIM | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs768516553; called by muse, mutect2, varscan2
- TCHH | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.724); catalogued as COSV64273841; called by muse, mutect2, varscan2
- TECPR2 | c.3539C>T p.A1180V | Missense Mutation (SNP) | VAF 52/405 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142102340; called by muse, mutect2, varscan2
- TENT5B | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.317); catalogued as rs1481749108, COSV56694062; called by muse, mutect2, varscan2
- TERT | c.2009C>T p.A670V | Missense Mutation (SNP) | VAF 44/263 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.121); catalogued as rs767382450, COSV57207796, COSV57229040; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TEX13C | c.1678del p.L560Wfs*9 | Frame Shift Del (DEL) | VAF 26/264 reads (10%) | catalogued as rs1156882988; called by pindel, varscan2
- TEX38 | c.493del p.L165Cfs*2 | Frame Shift Del (DEL) | VAF 20/169 reads (12%) | catalogued as rs776783500; called by mutect2, pindel, varscan2
- TFAP2E | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1277703444; called by muse, mutect2, varscan2
- TGFBR2 | c.446_448del p.F149del | In Frame Del (DEL) | VAF 24/225 reads (11%) | catalogued as rs1274930605; called by pindel, varscan2
- THAP5 | c.297del p.K99Nfs*25 (on ENST00000415914 / NM_001130475.3; = p.K57Nfs*25 on NM_182529.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as rs745348876; called by mutect2, varscan2
- TMC8 | c.422dup p.D142* | Frame Shift Ins (INS) | VAF 36/380 reads (9%) | catalogued as rs749599063; called by pindel, varscan2
- TMEM184A | c.400A>G p.S134G | Missense Mutation (SNP) | VAF 21/207 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as rs752272390; called by muse, mutect2, varscan2
- TMEM196 | c.192del p.K64Nfs*6 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs759398828; called by mutect2, varscan2
- TMEM53 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 10/250 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs973666259; called by muse, mutect2
- TNXB | c.7255G>A p.V2419M (on ENST00000647633; = p.V2172M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.131); catalogued as rs766408404; ClinVar: uncertain significance; called by muse, mutect2
- TRAF5 | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs547976158; called by muse, mutect2, varscan2
- TRAP1 | c.1728_1729del p.K577Gfs*107 | Frame Shift Del (DEL) | VAF 14/105 reads (13%) | catalogued as rs1567221728; called by pindel, varscan2
- TRIM45 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.115); catalogued as COSV56714886; called by muse, mutect2, varscan2
- TRPC4AP | c.2110C>T p.R704W | Missense Mutation (SNP) | VAF 42/362 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs958962560, COSV99328318; called by muse, mutect2
- TRPC5 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1410735076, COSV53305486; called by muse, mutect2, varscan2
- TRPM3 | c.2935G>A p.V979M (on ENST00000357533 / NM_001366142.2; = p.V822M on NM_020952.6) | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs760896360, COSV62582102; called by muse, mutect2, varscan2
- TRPM8 | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 34/290 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as rs201095192, COSV61222045; called by muse, mutect2, varscan2
- TRRAP | c.10544G>A p.R3515Q (on ENST00000359863 / NM_001244580.1; = p.R3486Q on NM_003496.3) | Missense Mutation (SNP) | VAF 39/338 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764504292; called by muse, mutect2, varscan2
- TRUB1 | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.693); catalogued as rs1397361545, COSV53928670; called by muse, mutect2
- TSPAN7 | c.516del p.S173Afs*4 | Frame Shift Del (DEL) | VAF 38/325 reads (12%) | catalogued as rs752121179, COSV54531581; called by mutect2, varscan2
- TTC25 | c.945G>T p.K315N | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV101103053; called by muse, mutect2
- TTF1 | c.614del p.G205Vfs*63 | Frame Shift Del (DEL) | VAF 16/160 reads (10%) | catalogued as rs1206439468; called by pindel, varscan2
- TTN | c.24581C>A p.A8194D (on ENST00000591111; = p.A7267D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/191 reads (10%) | PolyPhen probably damaging (0.993); catalogued as COSV59901003; called by muse, mutect2, varscan2
- TYW1B | c.1885G>A p.A629T | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.206); catalogued as rs782552126, COSV59269641; called by muse, mutect2, varscan2
- UBE2I | c.326_329del p.I109Nfs*5 | Frame Shift Del (DEL) | VAF 22/188 reads (12%) | catalogued as rs1317023497; called by mutect2, pindel, varscan2
- UBE3C | c.1964G>T p.R655L | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.245); catalogued as COSV61955453; called by muse, varscan2
- UCMA | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs556727126; called by muse, mutect2, varscan2
- UNC5B | c.2699C>T p.A900V | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.3); catalogued as rs898708834; called by muse, mutect2, varscan2
- VASN | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs757420411, COSV52030940; called by muse, mutect2, varscan2
- VAX1 | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs777113215; called by muse, mutect2, varscan2
- VPS13A | c.1115del p.K372Sfs*2 | Frame Shift Del (DEL) | VAF 26/174 reads (15%) | catalogued as rs770350986; called by mutect2, varscan2
- VPS9D1 | c.698G>C p.R233P | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.324); catalogued as rs770636061; called by muse, mutect2, varscan2
- VSIG10L | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs559064857; called by muse, mutect2, varscan2
- VWF | c.2072del p.P691Qfs*50 | Frame Shift Del (DEL) | VAF 29/303 reads (10%) | catalogued as rs267607309, CX1310905; ClinVar: not provided; called by mutect2, pindel
- WASHC2C | c.1032dup p.K345Qfs*25 | Frame Shift Ins (INS) | VAF 20/198 reads (10%) | catalogued as rs1397986573; called by mutect2, pindel
- WFIKKN1 | c.631G>A p.G211S | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs751716442, COSV50193655; called by muse, mutect2, varscan2
- WNT4 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 38/320 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.691); catalogued as rs369935449; called by mutect2, varscan2
- WNT7B | c.859G>A p.V287M | Missense Mutation (SNP) | VAF 48/361 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as rs780469731; called by muse, mutect2, varscan2
- WRAP73 | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 34/339 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs761435415; called by muse, mutect2, varscan2
- XPO4 | c.1411C>T p.R471* | Nonsense Mutation (SNP) | VAF 24/165 reads (15%) | catalogued as rs767410254, COSV55003807; called by muse, mutect2, varscan2
- XRCC1 | c.1568C>T p.T523M | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs765053443, COSV99486247; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 44/327 reads (13%) | catalogued as rs779864368; called by mutect2, varscan2
- ZBTB14 | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 53/351 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.293); catalogued as COSV63696428; called by muse, mutect2, varscan2
- ZBTB40 | c.786A>T p.L262F | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs1157137580; called by muse, mutect2
- ZC3H7B | c.1865G>A p.R622H | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); catalogued as rs374741632; called by muse, mutect2, varscan2
- ZHX2 | c.1310del p.P437Rfs*15 | Frame Shift Del (DEL) | VAF 25/227 reads (11%) | catalogued as rs1563602910; called by mutect2, pindel, varscan2
- ZMIZ1 | c.2468G>A p.R823Q | Missense Mutation (SNP) | VAF 34/262 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as rs945709533; called by muse, mutect2, varscan2
- ZNF292 | c.1360C>T p.R454* | Nonsense Mutation (SNP) | VAF 22/185 reads (12%) | catalogued as rs1215967523, COSV60543062; called by muse, mutect2, varscan2
- ZNF365 | c.1196del p.K399Sfs*6 | Frame Shift Del (DEL) | VAF 12/111 reads (11%) | catalogued as rs751774089; called by mutect2, varscan2
- ZNF423 | c.2743C>T p.R915W (on ENST00000563137 / NM_001379286.1; = p.R907W on NM_015069.4) | Missense Mutation (SNP) | VAF 26/255 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs544721667, COSV99283362; called by mutect2, varscan2
- ZNF438 | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 43/394 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs767079162, COSV100062823; called by muse, mutect2, varscan2
- ZNF462 | c.5347G>A p.V1783M | Missense Mutation (SNP) | VAF 35/268 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs771469581; called by muse, mutect2, varscan2
- ZNF462 | c.6800G>A p.R2267H | Missense Mutation (SNP) | VAF 34/288 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs756003963; called by muse, mutect2, varscan2
- ZNF469 | c.4835C>T p.A1612V (on ENST00000437464; = p.A1640V on NM_001367624.2) | Missense Mutation (SNP) | VAF 36/347 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.045); catalogued as rs867915419; called by muse, mutect2, varscan2
- ZNF516 | c.2653T>C p.Y885H | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV101487283; called by muse, mutect2
- ZNF699 | c.1655C>T p.T552M | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.937); catalogued as rs202037154; called by muse, mutect2
- ZNF708 | c.1251G>C p.K417N | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as rs1452222507; called by muse, mutect2
- ZNF77 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.159); catalogued as rs755151440, COSV58822623; called by muse, mutect2, varscan2
- ZNF785 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as COSV101235769; called by muse, mutect2, varscan2
- A3GALT2 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.005); called by muse, varscan2
- ABCA10 | c.515G>T p.R172L | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- ABCA4 | c.4128+2T>C p.X1376_splice | Splice Site (SNP) | VAF 30/289 reads (10%) | called by muse, mutect2, varscan2
- ABCA4 | c.2282C>T p.A761V | Missense Mutation (SNP) | VAF 58/529 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ABCD1 | c.2054A>G p.D685G | Missense Mutation (SNP) | VAF 30/260 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by mutect2, varscan2
- ABHD14B | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACADL | c.710del p.N237Mfs*3 | Frame Shift Del (DEL) | VAF 24/256 reads (9%) | called by mutect2, pindel, varscan2
- ACCSL | c.49G>T p.G17C | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACTR1A | c.845C>G p.A282G | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.37); called by muse, mutect2
- ADGB | c.1457del p.K486Rfs*5 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | called by pindel, varscan2
- AFF2 | c.1899del p.V634Lfs*121 | Frame Shift Del (DEL) | VAF 18/165 reads (11%) | called by mutect2, pindel, varscan2
- AJM1 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- AKAP17A | c.848A>G p.Q283R | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AKNA | c.842G>T p.R281M | Missense Mutation (SNP) | VAF 30/270 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- ALDH16A1 | c.17C>A p.A6E | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ALOX15 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- AMIGO3 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKRD12 | c.3448T>C p.Y1150H | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANKRD44 | c.2227G>A p.A743T | Missense Mutation (SNP) | VAF 14/300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- ANKRD65 | c.1158del p.E389Rfs*7 | Frame Shift Del (DEL) | VAF 11/101 reads (11%) | called by pindel, varscan2
- ANKS4B | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ANO1 | c.963-1G>T p.X321_splice | Splice Site (SNP) | VAF 14/78 reads (18%) | called by muse, mutect2, varscan2
- AP2B1 | c.2227A>G p.T743A | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.238); called by muse, mutect2
- ARAF | c.227C>T p.T76I | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- ARHGAP22 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 30/287 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ARHGEF2 | c.2909T>C p.I970T (on ENST00000361247 / NM_001162383.2; = p.I942T on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ARHGEF6 | c.1133T>C p.M378T | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.031); called by muse, mutect2
- ARID4B | c.2815del p.T939Rfs*2 | Frame Shift Del (DEL) | VAF 9/98 reads (9%) | called by mutect2, pindel
- ARMC7 | c.511del p.R171Afs*79 | Frame Shift Del (DEL) | VAF 29/289 reads (10%) | called by mutect2, pindel, varscan2
- ARPC3 | c.299T>G p.I100S | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); called by muse, varscan2
- ASCL1 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASH1L | c.3665del p.K1222Rfs*11 | Frame Shift Del (DEL) | VAF 28/213 reads (13%) | called by mutect2, pindel, varscan2
- ASTN1 | c.1385T>C p.L462P | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ATAD2B | c.3778_3781del p.E1260Lfs*8 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | called by mutect2, pindel, varscan2
- ATP1A1 | c.2557G>A p.A853T | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- ATP2B1 | c.3284A>G p.H1095R | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 42/384 reads (11%) | called by pindel, varscan2
- B3GNT6 | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- BAHCC1 | c.2440del p.H814Tfs*160 | Frame Shift Del (DEL) | VAF 10/87 reads (11%) | called by mutect2, pindel, varscan2
- BAHCC1 | c.4806del p.R1605Afs*107 | Frame Shift Del (DEL) | VAF 26/234 reads (11%) | called by mutect2, pindel, varscan2
- BRPF1 | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 39/317 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BSPRY | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.212); called by muse, mutect2
- BTBD3 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.544); called by muse, mutect2
- C11orf45 | c.135A>G p.T45= | Splice Region (SNP) | VAF 14/150 reads (9%) | called by muse, mutect2
- C11orf52 | c.251G>A p.C84Y | Missense Mutation (SNP) | VAF 60/413 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C2orf81 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAND2 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CARD8 | c.180del p.Q61Rfs*6 | Frame Shift Del (DEL) | VAF 12/89 reads (13%) | called by mutect2, varscan2
- CCDC127 | c.198del p.Q67Nfs*11 | Frame Shift Del (DEL) | VAF 13/122 reads (11%) | called by mutect2, pindel, varscan2
- CCDC168 | c.7708G>T p.V2570L | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CCDC8 | c.890dup p.E298Rfs*5 | Frame Shift Ins (INS) | VAF 29/188 reads (15%) | called by mutect2, pindel, varscan2
- CCDC88C | c.3566T>C p.I1189T | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- CCL3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CCNY | c.518G>T p.R173L | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CD248 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 63/429 reads (15%) | called by muse, mutect2, varscan2
- CD79A | c.298C>T p.H100Y | Missense Mutation (SNP) | VAF 85/720 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CDH13 | c.1223G>C p.G408A | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.6); called by muse, mutect2
- CDH18 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEACAM18 | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 29/322 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); called by muse, mutect2
- CELA3B | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP250 | c.2888A>G p.Q963R | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CFAP54 | c.1643C>A p.P548H | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CHADL | c.1324del p.R442Efs*34 | Frame Shift Del (DEL) | VAF 8/78 reads (10%) | called by mutect2, varscan2
- CHRM4 | c.1397A>G p.H466R | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHST2 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CIITA | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.736); called by muse, mutect2
- CLCN4 | c.391C>A p.L131M | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- CLTC | c.2554del p.R852Efs*4 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel
- CNGB3 | c.1321-2A>G p.X441_splice | Splice Site (SNP) | VAF 20/276 reads (7%) | called by muse, mutect2
- CNNM2 | c.1531del p.L511* | Frame Shift Del (DEL) | VAF 26/252 reads (10%) | called by mutect2, pindel
- COG5 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 15/329 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.339); called by muse, mutect2
- COL19A1 | c.2029G>A p.G677S | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL27A1 | c.4255del p.V1419Sfs*148 | Frame Shift Del (DEL) | VAF 14/174 reads (8%) | called by mutect2, pindel
- COL4A1 | c.2422G>A p.G808S | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- COL8A2 | c.920dup p.G308Wfs*34 | Frame Shift Ins (INS) | VAF 23/249 reads (9%) | called by mutect2, pindel
- CPSF1 | c.2473C>T p.Q825* | Nonsense Mutation (SNP) | VAF 46/431 reads (11%) | called by muse, mutect2, varscan2
- CUL4B | c.1193C>T p.A398V | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- CYP4V2 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 32/297 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DCDC2 | c.705T>A p.G235= | Splice Region (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2, varscan2
- DDTL | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DDX56 | c.298T>C p.S100P | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.116); called by muse, mutect2
- DDX58 | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- DDX60 | c.3248G>A p.W1083* | Nonsense Mutation (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- DHX38 | c.2772G>A p.M924I | Missense Mutation (SNP) | VAF 26/282 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2
- DIP2B | c.1105_1106del p.L369Yfs*18 | Frame Shift Del (DEL) | VAF 12/126 reads (10%) | called by pindel, varscan2
- DLGAP2 | c.2663A>G p.E888G | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- DNAH5 | c.1931del p.F644Sfs*8 | Frame Shift Del (DEL) | VAF 26/257 reads (10%) | called by mutect2, pindel, varscan2
- DOCK2 | c.1960G>C p.D654H | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DPP10 | c.508T>G p.L170V | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2
- DPP6 | c.779A>G p.N260S (on ENST00000377770 / NM_001364500.2; = p.N198S on NM_001936.5) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- DST | c.6050A>C p.E2017A | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2
- DYNC1H1 | c.2669T>C p.L890P | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EBF4 | c.768del p.C257Afs*63 (on ENST00000609451; = p.C253Afs*63 on NM_001110514.1) | Frame Shift Del (DEL) | VAF 20/181 reads (11%) | called by mutect2, pindel, varscan2
- EEF1AKMT4-ECE2 | c.2542G>A p.A848T | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- EFHC1 | c.515T>C p.I172T | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- EFNA1 | c.170A>G p.H57R | Missense Mutation (SNP) | VAF 31/288 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- EMB | c.224del p.N75Ifs*4 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | called by mutect2, pindel, varscan2
- EMILIN1 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 33/249 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- EP300 | c.5506C>T p.Q1836* | Nonsense Mutation (SNP) | VAF 18/412 reads (4%) | called by muse, mutect2
- EPHA7 | c.240C>A p.N80K | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2
- EPHX4 | c.515del p.G172Afs*2 | Frame Shift Del (DEL) | VAF 28/143 reads (20%) | called by mutect2, pindel, varscan2
- EPS15L1 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- EQTN | c.800C>T p.T267I | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESCO2 | c.796C>A p.L266I | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- EVPL | c.2489G>A p.C830Y | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EXOC7 | c.2158del p.V720Wfs*7 (on ENST00000335146 / NM_001145297.4; = p.V638Wfs*7 on NM_015219.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 21/208 reads (10%) | called by mutect2, pindel, varscan2
- EZHIP | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 26/303 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.205); called by muse, mutect2
- FAM111B | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2
- FAM126A | c.836C>G p.A279G | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.031); called by muse, mutect2
- FAM160B1 | c.2190T>C p.P730= | Splice Region (SNP) | VAF 16/151 reads (11%) | called by muse, mutect2, varscan2
- FAM170B | c.670C>A p.Q224K | Missense Mutation (SNP) | VAF 24/361 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.067); called by muse, mutect2
- FAM189B | c.1171dup p.L391Pfs*18 | Frame Shift Ins (INS) | VAF 18/160 reads (11%) | called by mutect2, pindel, varscan2
- FAM20B | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAM83H | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT2 | c.8854del p.L2952Wfs*80 | Frame Shift Del (DEL) | VAF 11/66 reads (17%) | called by mutect2, pindel, varscan2
- FBXO46 | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 29/238 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- FILIP1 | c.1881_1883del p.N627del | In Frame Del (DEL) | VAF 6/66 reads (9%) | called by pindel, varscan2
- FLRT2 | c.479G>A p.S160N | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.117); called by muse, mutect2
- FNBP4 | c.1704G>A p.W568* | Nonsense Mutation (SNP) | VAF 7/98 reads (7%) | called by muse, mutect2
- FNDC1 | c.3485C>A p.P1162H | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); called by muse, varscan2
- FOXC2 | c.1417G>T p.G473C | Missense Mutation (SNP) | VAF 19/251 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); called by muse, mutect2
- FOXP3 | c.808T>C p.S270P | Missense Mutation (SNP) | VAF 46/384 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FREM3 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT tolerated (0.85); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- FRY | c.4586C>T p.A1529V | Missense Mutation (SNP) | VAF 29/248 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- GALNT15 | c.409dup p.A137Gfs*2 | Frame Shift Ins (INS) | VAF 26/224 reads (12%) | called by mutect2, pindel, varscan2
- GALNT17 | c.924A>C p.K308N | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.698); called by mutect2, varscan2
- GDA | c.1241G>T p.G414V | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GJA8 | c.794G>A p.G265D | Missense Mutation (SNP) | VAF 32/489 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- GOLGA6L6 | c.443C>G p.A148G | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- GPC4 | c.1450G>A p.V484M | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GPR25 | c.991C>T p.R331* | Nonsense Mutation (SNP) | VAF 25/194 reads (13%) | called by muse, mutect2, varscan2
- GRIK2 | c.1745C>A p.A582D | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM7 | c.1375+2T>C p.X459_splice | Splice Site (SNP) | VAF 12/97 reads (12%) | called by muse, mutect2, varscan2
- GZF1 | c.1931del p.N644Mfs*50 | Frame Shift Del (DEL) | VAF 30/288 reads (10%) | called by mutect2, varscan2
- HAP1 | c.966G>T p.R322S | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- HAS1 | c.167T>C p.F56S | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HAUS4 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HDAC11 | c.1031del p.P344Lfs*26 | Frame Shift Del (DEL) | VAF 34/302 reads (11%) | called by mutect2, pindel, varscan2
- HIVEP3 | c.6223G>T p.G2075C | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- HOXA13 | c.641C>G p.A214G | Missense Mutation (SNP) | VAF 33/397 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.349); called by muse, mutect2
- HSPG2 | c.7136del p.G2379Afs*14 | Frame Shift Del (DEL) | VAF 51/431 reads (12%) | called by mutect2, pindel, varscan2
- HYDIN | c.8114G>T p.R2705M | Missense Mutation (SNP) | VAF 27/318 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2
- IGF2BP3 | c.1503_1504del p.R501Sfs*11 | Frame Shift Del (DEL) | VAF 8/88 reads (9%) | called by pindel, varscan2
- IKZF3 | c.1403C>T p.T468M | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IRX2 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 64/465 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGB2 | c.1250G>T p.R417M (on ENST00000302347; = p.R393M on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/608 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- ITK | c.1095del p.F365Lfs*40 | Frame Shift Del (DEL) | VAF 38/369 reads (10%) | called by mutect2, pindel, varscan2
- ITPR3 | c.2763del p.H922Tfs*2 | Frame Shift Del (DEL) | VAF 14/113 reads (12%) | called by mutect2, pindel, varscan2
- JARID2 | c.1272del p.R425Gfs*36 | Frame Shift Del (DEL) | VAF 11/97 reads (11%) | called by mutect2, pindel, varscan2
- KCNMA1 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.011); called by muse, mutect2
- KCTD16 | c.874T>C p.C292R | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.083); called by muse, mutect2
- KIAA0753 | c.2867C>T p.A956V | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KIT | c.17G>A p.G6D | Missense Mutation (SNP) | VAF 43/309 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- KLHL5 | c.787dup p.M263Nfs*22 | Frame Shift Ins (INS) | VAF 10/73 reads (14%) | called by mutect2, pindel, varscan2
- KMT2D | c.7891G>T p.G2631* | Nonsense Mutation (SNP) | VAF 31/287 reads (11%) | called by muse, mutect2, varscan2
- LAMA5 | c.2374C>T p.P792S | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- LAMC3 | c.1281C>T p.C427= | Splice Region (SNP) | VAF 44/505 reads (9%) | called by muse, mutect2
- LCN12 | c.496C>A p.L166M | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LCT | c.4519G>A p.E1507K | Missense Mutation (SNP) | VAF 22/275 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); called by muse, mutect2
- LHCGR | c.1764del p.F588Lfs*14 | Frame Shift Del (DEL) | VAF 23/237 reads (10%) | called by mutect2, pindel
- LHX4 | c.293del p.P98Qfs*75 | Frame Shift Del (DEL) | VAF 39/394 reads (10%) | called by mutect2, pindel, varscan2
- LLGL2 | c.1763dup p.A589Gfs*11 | Frame Shift Ins (INS) | VAF 23/234 reads (10%) | called by mutect2, pindel, varscan2
- LNPEP | c.1887del p.F629Lfs*9 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel, varscan2
- LOXHD1 | c.100dup p.E34Gfs*13 | Frame Shift Ins (INS) | VAF 19/161 reads (12%) | called by mutect2, pindel, varscan2
- LRRC4C | c.381C>A p.N127K | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.225); called by muse, mutect2
- LRRC71 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- LRRC8B | c.1865C>T p.T622I | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2
- LRRTM1 | c.398del p.F133Sfs*92 | Frame Shift Del (DEL) | VAF 29/257 reads (11%) | called by mutect2, pindel, varscan2
- LTBP4 | c.2068C>A p.L690M (on ENST00000308370 / NM_001042544.1; = p.L653M on NM_003573.2) | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- LTN1 | c.325A>T p.I109F | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MAN1B1 | c.1769C>T p.A590V | Missense Mutation (SNP) | VAF 61/494 reads (12%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.466); called by mutect2, varscan2
- MAN2A1 | c.2447C>T p.A816V | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MAP7D2 | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 13/109 reads (12%) | called by muse, mutect2, varscan2
- MAPKAPK5 | c.693_696del p.I231Mfs*2 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | called by mutect2, pindel, varscan2
- MBD6 | c.951del p.F318Sfs*59 | Frame Shift Del (DEL) | VAF 21/150 reads (14%) | called by mutect2, pindel, varscan2
- MCF2 | c.780del p.K260Nfs*5 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | called by mutect2, pindel, varscan2
- MCM3AP | c.2628+2T>C p.X876_splice | Splice Site (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- MED16 | c.349A>G p.S117G | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- MEGF10 | c.244C>T p.H82Y | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.222); called by muse, mutect2
- METTL11B | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 36/346 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- MGAM2 | c.741del p.T248Pfs*4 | Frame Shift Del (DEL) | VAF 12/80 reads (15%) | called by mutect2, pindel, varscan2
- MIA2 | c.1308_1310del p.E436del | In Frame Del (DEL) | VAF 4/24 reads (17%) | called by pindel, varscan2
- MICAL2 | c.4314G>T p.L1438F | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- MINDY2 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MINK1 | c.284dup p.N97Kfs*3 | Frame Shift Ins (INS) | VAF 13/139 reads (9%) | called by mutect2, pindel
- MMP28 | c.934_935insT p.Q312Lfs*6 | Frame Shift Ins (INS) | VAF 17/134 reads (13%) | called by mutect2, pindel, varscan2
- MMP28 | c.691G>A p.G231R | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- MOG | c.81C>A p.S27R | Missense Mutation (SNP) | VAF 16/253 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0.218); called by muse, mutect2
- MROH7 | c.67T>C p.S23P | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); called by muse, mutect2
- MSH6 | c.2737G>A p.D913N | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); called by muse, mutect2
- MTUS1 | c.2107del p.T703Qfs*17 | Frame Shift Del (DEL) | VAF 8/92 reads (9%) | called by mutect2, pindel
- MYBPC2 | c.3419C>A p.P1140Q | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MYBPC3 | c.1360G>C p.V454L | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- MYCBP2 | c.10348C>T p.H3450Y (on ENST00000357337; = p.H3488Y on NM_015057.5) | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- MYH4 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2
- MYO18A | c.4617G>T p.K1539N | Missense Mutation (SNP) | VAF 44/398 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- MYO1H | c.2084del p.F695Sfs*19 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | called by mutect2, pindel, varscan2
- NAP1L3 | c.1474T>C p.Y492H | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- NCAPD2 | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NCF2 | c.107A>G p.H36R | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2
- NDUFC2 | c.65del p.P22Rfs*4 | Frame Shift Del (DEL) | VAF 11/91 reads (12%) | called by mutect2, pindel, varscan2
- NEB | c.1837A>G p.S613G | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); called by muse, mutect2
- NEFM | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 17/340 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- NEO1 | c.551G>A p.R184K | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.685); called by muse, mutect2
- NFYC | c.461C>A p.A154D | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- NID1 | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 43/353 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NKAP | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- NOL8 | c.2738del p.K913Rfs*4 | Frame Shift Del (DEL) | VAF 11/78 reads (14%) | called by mutect2, pindel, varscan2
- NPRL3 | c.913G>A p.A305T (on ENST00000611875 / NM_001077350.3; = p.A280T on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NR4A2 | c.881del p.N294Mfs*7 | Frame Shift Del (DEL) | VAF 40/342 reads (12%) | called by mutect2, varscan2
- NRG1 | c.979G>C p.E327Q (on ENST00000405005 / NM_013964.5; = p.E332Q on NM_013956.5) | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2
- NSD3 | c.4214G>A p.C1405Y | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NTN3 | c.1389C>A p.D463E | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NUP133 | c.648+2T>C p.X216_splice | Splice Site (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- NUP93 | c.518del p.P173Lfs*25 | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | called by pindel, varscan2
- NUTM1 | c.224_225insC p.G76Wfs*25 | Frame Shift Ins (INS) | VAF 33/297 reads (11%) | called by mutect2, pindel*
- OMG | c.467A>G p.N156S | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR10X1 | c.257A>C p.E86A | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- OR1B1 | c.386G>A p.C129Y | Missense Mutation (SNP) | VAF 36/354 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2A14 | c.153C>A p.D51E | Missense Mutation (SNP) | VAF 26/282 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.048); called by muse, mutect2
- OSER1 | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- OSGEP | c.855del p.F285Lfs*14 | Frame Shift Del (DEL) | VAF 24/181 reads (13%) | called by mutect2, pindel, varscan2
- OSMR | c.1836A>C p.L612F | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2
- PACSIN2 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 41/399 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PCDH15 | c.1391C>T p.T464I | Missense Mutation (SNP) | VAF 23/231 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.673); called by muse, mutect2
- PCDH17 | c.3085C>A p.L1029I | Missense Mutation (SNP) | VAF 40/315 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.714); called by mutect2, varscan2
- PCIF1 | c.1897T>C p.Y633H | Missense Mutation (SNP) | VAF 34/298 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCSK7 | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 22/395 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- PDCD11 | c.5329G>A p.A1777T | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PDE4DIP | c.1850G>A p.C617Y | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.96); called by muse, mutect2
- PHC2 | c.1557_1558del p.E519Dfs*37 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | called by pindel, varscan2
- PHYHD1 | c.789C>A p.H263Q (on ENST00000372592 / NM_001100876.2; = p.T256N on NM_174933.4) | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PIEZO2 | c.752del p.L251Wfs*33 | Frame Shift Del (DEL) | VAF 11/99 reads (11%) | called by mutect2, pindel, varscan2
- PKD1L1 | c.7448C>T p.T2483I | Missense Mutation (SNP) | VAF 38/436 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- PKP4 | c.3400C>T p.Q1134* | Nonsense Mutation (SNP) | VAF 10/107 reads (9%) | called by muse, mutect2
532 further variants in this file (119 protein-altering or splice-affecting, 261 silent, 152 other) are not listed here.
